Somatic mutation profile of tumor specimen TARGET-20-PARUAD-09A (aliquot TARGET-20-PARUAD-09A-01D) from TARGET case TARGET-20-PARUAD, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.7 years (3,163 days).
Specimen TARGET-20-PARUAD-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e22eaa32-ff0c-4653-8a1a-7941b7dbb812.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARUAD-14A (Bone Marrow Normal), aliquot TARGET-20-PARUAD-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8e87a619-12c3-41ac-b408-c6f055b6801b

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2508_2510del p.I836del | In Frame Del (DEL) | VAF 81/459 reads (18%) | catalogued as rs121913490; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- FLT3 | c.2028C>A p.N676K | Missense Mutation (SNP) | VAF 16/432 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519766, COSV54042688, COSV54051954; ClinVar: likely pathogenic; called by muse, mutect2
- NCAM1 | c.1562A>G p.Y521C (on ENST00000316851 / NM_181351.5; = p.Y511C on NM_000615.7) | Missense Mutation (SNP) | VAF 20/246 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2
